Somatic mutation profile of tumor specimen CDDP-ABL8-TTP1-C (aliquot CDDP-ABL8-TTP1-C-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABL8, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60 years.
Specimen CDDP-ABL8-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00f075e6-aa96-401e-9bb8-e7368add6cca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABL8-NB1-A (Blood Derived Normal), aliquot CDDP-ABL8-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d66fcd4-80c0-477f-bb1e-87ec719eb7b0

The open-access MAF lists 236 somatic variants for this specimen: 153 protein-altering or splice-affecting, 60 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 60, Intron 13, Splice Site 7, RNA 5, Nonsense Mutation 4, Frame Shift Del 4, 3'UTR 2, Translation Start Site 1, 5'Flank 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 102/301 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.402G>C p.M134I | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1114167676, CM1211213, COSV64291845, COSV64293372, COSV64295066; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.761T>G p.I254S | Missense Mutation (SNP) | VAF 50/225 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330865474, CM151471, COSV52674699, COSV52714188, COSV52767322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX15B | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 82/357 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1323756895; called by muse, mutect2, varscan2
- ALPK2 | c.2041T>A p.S681T | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs528527919, COSV64494596; called by muse, mutect2, varscan2
- ANKRD44 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99986102; called by muse, mutect2, varscan2
- AP1AR | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV56768764; called by muse, mutect2, varscan2
- AP1AR | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV56769282; called by muse, mutect2, varscan2
- ATP8A2 | c.1268A>C p.K423T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54963493; called by muse, mutect2, varscan2
- BRINP3 | c.1483C>A p.L495I | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV66514384, COSV66531266; called by muse, mutect2, varscan2
- C19orf71 | c.448+1del | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as COSV61536787; called by mutect2, pindel, varscan2
- CACNA1B | c.2615C>T p.P872L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1373834536, COSV53111948; called by muse, mutect2
- CAPN13 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as COSV54432702; called by muse, mutect2
- CCDC168 | c.6177G>A p.M2059I | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as COSV70555138; called by muse, mutect2, varscan2
- CENPE | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54382834; called by muse, mutect2, varscan2
- CFAP47 | c.2093G>T p.R698I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV52888200, COSV52891034; called by muse, mutect2, varscan2
- CFHR1 | c.643G>C p.D215H | Missense Mutation (SNP) | VAF 92/672 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV57627970, COSV57628658; called by muse, mutect2, varscan2
- CHD6 | c.7155G>C p.Q2385H | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV64690955; called by muse, mutect2, varscan2
- CLASP1 | c.4489G>A p.E1497K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55313096; called by muse, mutect2, varscan2
- CRB1 | c.1516T>G p.S506A | Missense Mutation (SNP) | VAF 54/349 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.106); catalogued as COSV66331677; called by muse, mutect2, varscan2
- CRB1 | c.2783G>C p.C928S | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as CM1511478; called by muse, mutect2, varscan2
- CRLS1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1188126910; called by muse, mutect2, varscan2
- CSMD2 | c.8234G>T p.G2745V | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53932207; called by muse, mutect2, varscan2
- CSNK2A2 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV104390676; called by muse, mutect2, varscan2
- CYP3A4 | c.1513C>T p.P505S (on ENST00000336411; = p.P474S on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV60503111; called by muse, mutect2, varscan2
- DCHS1 | c.8525G>T p.G2842V | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV54998051; called by muse, mutect2, varscan2
- DCHS1 | c.4646C>A p.P1549Q | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55033544; called by muse, mutect2, varscan2
- DNAJC6 | c.2439G>T p.K813N | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV54778208; called by muse, mutect2, varscan2
- DOCK4 | c.5071A>C p.S1691R | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs776427871, COSV70240008; called by muse, mutect2, varscan2
- DOCK6 | c.3311G>A p.R1104Q | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs570124917, COSV53917929; called by muse, mutect2, varscan2
- EPHA8 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.061); catalogued as COSV51277467; called by muse, mutect2, varscan2
- FAM161A | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56767056; called by muse, mutect2, varscan2
- FANCD2 | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99810739; called by muse, mutect2, varscan2
- FLII | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58946301; called by muse, mutect2, varscan2
- FMO2 | c.1390T>C p.Y464H | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52949062; called by muse, mutect2, varscan2
- FMR1NB | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.534); catalogued as COSV65071541; called by muse, mutect2, varscan2
- FYB1 | c.225C>G p.D75E | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV60956460; called by muse, mutect2, varscan2
- GRK1 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs372061074; called by muse, mutect2, varscan2
- INTS8 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV58251965; called by muse, mutect2, varscan2
- IQCH | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.133); catalogued as rs762746850, COSV60056210; called by muse, mutect2, varscan2
- ITPRID2 | c.657T>A p.F219L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV57474087; called by muse, mutect2, varscan2
- KDM2A | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1385596955; called by muse, mutect2, varscan2
- KIF6 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761775394, COSV54679262; called by muse, mutect2, varscan2
- KLHL31 | c.1245C>A p.S415R | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs757817861; called by muse, mutect2, varscan2
- LRP1B | c.3163G>A p.G1055R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.99); catalogued as rs769461582, COSV67233601; called by muse, mutect2, varscan2
- MAP3K20 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs1206359758, COSV59104812; called by muse, mutect2, varscan2
- MNX1 | c.1024A>T p.K342* | Nonsense Mutation (SNP) | VAF 62/370 reads (17%) | catalogued as rs1365706841; called by muse, mutect2, varscan2
- MTMR10 | c.1276A>G p.R426G | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58728894; called by muse, mutect2, varscan2
- MUC16 | c.28106C>A p.P9369H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV67458819; called by muse, mutect2, varscan2
- MUC17 | c.5224T>G p.S1742A | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV60286997; called by muse, mutect2, varscan2
- NAALAD2 | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58963277; called by muse, mutect2, varscan2
- NLRC3 | c.2525G>C p.R842P | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373104014; called by muse, mutect2, varscan2
- OR11G2 | c.776T>A p.V259D | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62132717, COSV62133151; called by muse, mutect2, varscan2
- OR4S1 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100180311; called by muse, mutect2, varscan2
- OR8J3 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56882515; called by muse, mutect2, varscan2
- PCDHA3 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.877); catalogued as rs1290587407, COSV100793021; called by muse, mutect2
- PCID2 | c.737A>G p.K246R | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs750407249; called by muse, mutect2, varscan2
- PDE3B | c.2534A>G p.N845S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56390022; called by muse, mutect2, varscan2
- PLCB3 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as rs1230584686; called by muse, mutect2, varscan2
- POSTN | c.1381G>T p.V461L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV65713673; called by muse, mutect2
- POTEE | c.2165C>A p.A722E | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs543549731; called by muse, mutect2, varscan2
- PTPRF | c.1391A>C p.K464T | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV63446668; called by muse, mutect2, varscan2
- PWWP3A | c.172G>C p.E58Q (on ENST00000627377; = p.E57Q on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV60901913; called by muse, mutect2, varscan2
- RNF213 | c.2642T>C p.L881P | Missense Mutation (SNP) | VAF 82/400 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60626735; called by muse, mutect2, varscan2
- RNF213 | c.10409G>A p.G3470E | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60402732; called by muse, mutect2, varscan2
- ROS1 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as rs1562400768, COSV63857923; called by muse, mutect2, varscan2
- SERPINB7 | c.205T>A p.S69T | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.253); catalogued as COSV60534850; called by muse, mutect2, varscan2
- SF3B5 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 78/442 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62451412; called by muse, mutect2
- SIN3B | c.1946A>C p.E649A | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV56134610; called by muse, mutect2, varscan2
- SPOCK3 | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV62740903; called by muse, mutect2, varscan2
- SRSF12 | c.761G>C p.S254T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV71683726; called by muse, mutect2, varscan2
- SULT1E1 | c.663G>C p.R221S | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56947811; called by muse, mutect2, varscan2
- SYNE1 | c.14986C>T p.Q4996* (on ENST00000367255 / NM_182961.4; = p.Q4925* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 38/170 reads (22%) | catalogued as COSV54951045, COSV55033747; called by muse, mutect2, varscan2
- TARDBP | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV53570555; called by muse, mutect2, varscan2
- UNC79 | c.5636T>A p.L1879* (on ENST00000393151 / NM_001346218.2; = p.L1702* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 42/184 reads (23%) | catalogued as COSV56397645; called by muse, mutect2, varscan2
- USP19 | c.1486T>C p.F496L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60047140; called by muse, mutect2, varscan2
- VWA3B | c.2744T>G p.L915R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68244570; called by muse, mutect2
- WDFY3 | c.305-1G>C p.X102_splice | Splice Site (SNP) | VAF 18/91 reads (20%) | catalogued as COSV55702977; called by muse, mutect2, varscan2
- WWP2 | c.1547A>C p.K516T | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63126089; called by muse, mutect2, varscan2
- ZC3H13 | c.2769G>C p.Q923H | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.34); catalogued as rs955053802, COSV54449850; called by muse, mutect2, varscan2
- ZFHX4 | c.1017A>C p.K339N | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50657758; called by muse, mutect2, varscan2
- ZFYVE16 | c.155G>C p.R52P | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV62016421; called by muse, varscan2
- ZFYVE28 | c.511T>G p.F171V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52114175; called by muse, varscan2
- ZNF407 | c.1416T>A p.D472E | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV104401227; called by muse, mutect2, varscan2
- ZNF844 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs781304308, COSV71518617; called by muse, mutect2, varscan2
- AARS2 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCB1 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- ACTN3 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ADGRL2 | c.3563A>G p.N1188S | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ALYREF | c.539-1G>C p.X180_splice | Splice Site (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- ARFIP1 | c.87T>A p.F29L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ARHGEF10L | c.2140C>G p.L714V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ARHGEF3 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- BMP2 | c.971A>T p.Y324F | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CAMSAP1 | c.3040G>A p.V1014I | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CAMTA2 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CCDC144A | c.3127T>A p.S1043T | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CCDC65 | c.199A>C p.T67P | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); called by muse, mutect2
- CCDC74A | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLCN1 | c.1648A>G p.T550A | Missense Mutation (SNP) | VAF 46/456 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COPS6 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRHR1 | c.643-1G>T p.X215_splice (on ENST00000398285 / NM_001145146.2; = p.X186_splice on NM_004382.5) | Splice Site (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- CYB561 | c.278T>G p.F93C | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- DCAF4 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- DMRT2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DPP6 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- EIF3M | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- EIF4G2 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.353); called by muse, mutect2
- EPHA6 | c.2351C>A p.P784Q (on ENST00000389672 / NM_001080448.3; = p.P176Q on NM_173655.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- EPSTI1 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, varscan2
- EPSTI1 | c.583A>C p.S195R | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, varscan2
- EPX | c.346+1_346+5del p.X116_splice | Splice Site (DEL) | VAF 48/237 reads (20%) | called by mutect2, pindel, varscan2
- EXOC2 | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FOXI3 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by mutect2, varscan2
- FREM3 | c.1570_1571delinsC p.G524Rfs*44 | Frame Shift Del (DEL) | VAF 33/198 reads (17%) | called by pindel, varscan2*
- GOLGA6L10 | c.409T>G p.L137V | Missense Mutation (SNP) | VAF 35/622 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- HLX | c.1140C>G p.D380E | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HNRNPH1 | c.-1_16del | Translation Start Site (DEL) | VAF 17/170 reads (10%) | called by mutect2, pindel
- IGHA2 | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 90/451 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- IL1RL1 | c.737T>C p.L246S | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- IMPG1 | c.1716G>C p.E572D | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR2 | c.3490G>T p.D1164Y | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- JCAD | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIF4B | c.2592G>T p.K864N | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRTAP19-7 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- LYPD6 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MED24 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAM2 | c.2164-1G>C p.X722_splice | Splice Site (SNP) | VAF 25/225 reads (11%) | called by muse, mutect2, varscan2
- MRPL45 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NGDN | c.851del p.G284Efs*? (on ENST00000408901 / NM_001042635.2; = p.G284Efs*35 on NM_015514.2) | Frame Shift Del (DEL) | VAF 32/131 reads (24%) | called by mutect2, pindel, varscan2
- NUP35 | c.41-11_41-1delinsTTTTTTTTTAT p.X14_splice | Splice Site (ONP) | VAF 6/61 reads (10%) | called by muse*, pindel
- PID1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | PolyPhen benign (0.292); called by muse, varscan2
- PRAMEF1 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 61/353 reads (17%) | called by muse, mutect2, varscan2
- PRR36 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PRRC2C | c.6457G>A p.D2153N (on ENST00000367742; = p.D2151N on NM_015172.4) | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PRX | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 109/511 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- PTK6 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRT | c.860-2A>G p.X287_splice | Splice Site (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2
- RHNO1 | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- RP1 | c.3350T>G p.F1117C | Missense Mutation (SNP) | VAF 78/570 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SEMA6A | c.257C>A p.T86K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SERTAD1 | c.334_335del p.A113Lfs*13 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- SETBP1 | c.2254G>T p.V752F | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.387); called by muse, mutect2
- SH2D3A | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SIPA1L3 | c.1932G>C p.E644D | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- SLC26A5 | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SORT1 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPTA1 | c.6908T>A p.L2303H | Missense Mutation (SNP) | VAF 67/445 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TENM1 | c.3355A>T p.R1119W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TRIM37 | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC26 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- USP24 | c.1823G>T p.W608L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFYVE28 | c.490T>G p.F164V | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- ADAM19 | c.2292T>G p.T764= | Silent (SNP) | VAF 32/261 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.2364G>T p.V788= | Silent (SNP) | VAF 46/308 reads (15%) | called by muse, mutect2, varscan2
- AFF2 | c.1287G>C p.L429= | Silent (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- AKR7L | c.345C>T p.D115= | Silent (SNP) | VAF 52/264 reads (20%) | called by muse, mutect2, varscan2
- ANPEP | c.2790C>T p.F930= | Silent (SNP) | VAF 39/217 reads (18%) | catalogued as rs145116014; called by muse, mutect2, varscan2
- ASB1 | c.684A>C p.T228= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as COSV52827621; called by muse, mutect2, varscan2
- BIRC7 | c.117C>A p.V39= | Silent (SNP) | VAF 34/182 reads (19%) | called by muse, mutect2, varscan2
- BRINP2 | c.246C>T p.F82= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, varscan2
- C7 | c.21C>T p.F7= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as rs865977092, COSV57476953; called by muse, mutect2, varscan2
- CD248 | c.897T>G p.G299= | Silent (SNP) | VAF 57/242 reads (24%) | catalogued as COSV60937123; called by muse, mutect2, varscan2
- CD27 | c.651T>C p.Y217= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as rs537450252, COSV56947697; called by muse, mutect2, varscan2
- CEP192 | c.1885A>C p.R629= | Silent (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- CHRDL1 | c.138T>A p.P46= (on ENST00000372045; = p.P52= on NM_145234.4) | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, varscan2
- CT47B1 | c.567G>T p.L189= | Silent (SNP) | VAF 100/258 reads (39%) | catalogued as rs753812300, COSV64891034, COSV64891180; called by muse, mutect2, varscan2
- DERA | c.390A>T p.P130= | Silent (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- DGKB | c.2364C>T p.T788= | Silent (SNP) | VAF 30/207 reads (14%) | catalogued as rs919086784, COSV51799915; called by muse, mutect2, varscan2
- ELF1 | c.1416A>G p.P472= | Silent (SNP) | VAF 39/214 reads (18%) | called by muse, mutect2, varscan2
- EPX | c.1098G>A p.A366= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as rs201800086, COSV56597039; called by muse, mutect2, varscan2
- ERICH3 | c.3354C>A p.P1118= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as COSV58612114; called by muse, mutect2, varscan2
- EVA1C | c.672A>C p.R224= | Silent (SNP) | VAF 58/187 reads (31%) | catalogued as COSV55825388; called by muse, mutect2, varscan2
- FASTKD2 | c.1344T>G p.P448= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV52699185; called by muse, mutect2, varscan2
- FOXI3 | c.366G>T p.A122= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV101230916; called by muse, mutect2, varscan2
- FUBP3 | c.354T>C p.S118= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- GCKR | c.1590C>T p.S530= | Silent (SNP) | VAF 45/275 reads (16%) | catalogued as rs1248727656, COSV53109359; called by muse, mutect2, varscan2
- GSDMC | c.711C>G p.T237= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV52697036; called by muse, mutect2, varscan2
- GSR | c.589C>T p.L197= | Silent (SNP) | VAF 66/206 reads (32%) | catalogued as rs1407891110; called by muse, mutect2, varscan2
- HLA-G | c.693C>A p.G231= | Silent (SNP) | VAF 32/218 reads (15%) | called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.57C>A p.S19= | Silent (SNP) | VAF 32/174 reads (18%) | called by muse, mutect2, varscan2
- INSM2 | c.1170G>A p.L390= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV51889067; called by muse, mutect2, varscan2
- INTS5 | c.1632C>G p.V544= | Silent (SNP) | VAF 56/282 reads (20%) | catalogued as rs1482030155; called by muse, mutect2, varscan2
- KRTAP15-1 | c.120C>T p.T40= | Silent (SNP) | VAF 7/158 reads (4%) | catalogued as COSV61878294; called by muse, mutect2
- LRRC31 | c.1447C>T p.L483= | Silent (SNP) | VAF 66/251 reads (26%) | catalogued as COSV52981720; called by muse, mutect2, varscan2
- LRRTM4 | c.1629A>T p.P543= | Silent (SNP) | VAF 32/236 reads (14%) | called by muse, mutect2, varscan2
- LZTS1 | c.1293G>C p.L431= | Silent (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- MAF | c.960G>A p.K320= | Silent (SNP) | VAF 83/562 reads (15%) | catalogued as rs762044711; called by muse, mutect2, varscan2
- MMP16 | c.399T>G p.T133= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs1458204525, COSV54165430, COSV99687648; called by muse, mutect2, varscan2
- MYH1 | c.4686C>A p.I1562= | Silent (SNP) | VAF 26/180 reads (14%) | catalogued as rs779996545; called by muse, mutect2, varscan2
- MYH8 | c.1329C>T p.V443= | Silent (SNP) | VAF 111/624 reads (18%) | catalogued as COSV67970587; called by muse, mutect2, varscan2
- NCAPH | c.1863G>A p.L621= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV53637387; called by muse, mutect2, varscan2
- NELL2 | c.2103C>A p.L701= | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as COSV61579526; called by muse, mutect2, varscan2
- NELL2 | c.1020C>A p.T340= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV61582668; called by muse, mutect2, varscan2
- NLRP3 | c.879C>A p.S293= | Silent (SNP) | VAF 51/180 reads (28%) | catalogued as COSV60227956; called by muse, mutect2, varscan2
- OBSCN | c.13368C>T p.S4456= | Silent (SNP) | VAF 33/175 reads (19%) | catalogued as rs1231231846, COSV52741685; called by muse, varscan2
- OR8K3 | c.837G>T p.L279= | Silent (SNP) | VAF 57/251 reads (23%) | catalogued as COSV57132198; called by muse, mutect2, varscan2
- PAMR1 | c.1065G>A p.V355= (on ENST00000619888 / NM_001001991.3; = p.V372= on NM_015430.4) | Silent (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- PAPPA | c.1104G>A p.P368= | Silent (SNP) | VAF 55/420 reads (13%) | catalogued as rs1232382704, COSV60291676; called by muse, mutect2, varscan2
- PAX1 | c.723G>A p.P241= | Silent (SNP) | VAF 13/177 reads (7%) | catalogued as rs1434161578, COSV68271351; called by muse, mutect2
- PCDHA3 | c.1107C>A p.I369= | Silent (SNP) | VAF 42/200 reads (21%) | catalogued as rs1554122016; called by muse, mutect2
- PIP5K1A | c.852A>C p.L284= (on ENST00000368888 / NM_001135638.2; = p.L271= on NM_003557.3) | Silent (SNP) | VAF 34/298 reads (11%) | called by muse, varscan2
- PRDM7 | c.996C>A p.A332= | Silent (SNP) | VAF 101/547 reads (18%) | called by muse, mutect2, varscan2
- PTPRB | c.660A>T p.T220= | Silent (SNP) | VAF 62/307 reads (20%) | called by muse, mutect2, varscan2
- RNF213 | c.1623G>A p.L541= | Silent (SNP) | VAF 80/403 reads (20%) | catalogued as COSV60619233; called by muse, mutect2, varscan2
- SF3B5 | c.111C>T p.R37= | Silent (SNP) | VAF 80/461 reads (17%) | catalogued as COSV62451408; called by muse, mutect2
- SGIP1 | c.915T>A p.A305= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as COSV52766726, COSV52773516; called by muse, mutect2, varscan2
- SLC38A11 | c.138T>G p.T46= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV58053507; called by muse, mutect2, varscan2
- TAF1C | c.1188C>T p.H396= | Silent (SNP) | VAF 57/270 reads (21%) | catalogued as rs1489732213, COSV58987583; called by muse, mutect2, varscan2
- TMC6 | c.48G>A p.G16= | Silent (SNP) | VAF 52/315 reads (17%) | catalogued as rs199831098, COSV59210484; ClinVar: likely benign; called by muse, mutect2, varscan2
- TOB1 | c.612T>G p.T204= | Silent (SNP) | VAF 48/239 reads (20%) | catalogued as COSV52151163; called by muse, mutect2, varscan2
- TUBAL3 | c.747C>T p.L249= | Silent (SNP) | VAF 55/168 reads (33%) | catalogued as rs1016746088; called by muse, mutect2, varscan2
- ZSWIM3 | c.531G>A p.V177= | Silent (SNP) | VAF 29/153 reads (19%) | called by muse, mutect2, varscan2
- AC005865.1 | chr12:3298232 C>A | 3'Flank (SNP) | VAF 70/209 reads (33%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4320A>G | RNA (SNP) | VAF 28/195 reads (14%) | called by muse, mutect2, varscan2
- AC092745.2 | n.47-11936C>T | Intron (SNP) | VAF 44/236 reads (19%) | called by muse, mutect2, varscan2
- BNC2 | c.2639+5618G>T | Intron (SNP) | VAF 16/133 reads (12%) | catalogued as rs772117084; called by muse, mutect2, varscan2
- GUSBP10 | n.327G>T | RNA (SNP) | VAF 75/205 reads (37%) | called by muse, mutect2, varscan2
- LAMP2 | c.1093+2617A>T | Intron (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85684C>A | Intron (SNP) | VAF 75/427 reads (18%) | catalogued as COSV72280362; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85685C>A | Intron (SNP) | VAF 78/427 reads (18%) | catalogued as COSV72280364; called by muse, mutect2, varscan2
- MT1E | c.95-170G>C | Intron (SNP) | VAF 47/259 reads (18%) | called by muse, mutect2, varscan2
- NDUFS1 | c.-5+219G>C | Intron (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2
- NPIPP1 | n.792C>T | RNA (SNP) | VAF 81/431 reads (19%) | catalogued as rs1416897223; called by muse, mutect2, varscan2
- NRP1 | c.1925-2347C>A | Intron (SNP) | VAF 33/175 reads (19%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.630G>A | RNA (SNP) | VAF 44/355 reads (12%) | called by muse, mutect2, varscan2
- RALA | c.498+556C>A | Intron (SNP) | VAF 37/247 reads (15%) | called by muse, mutect2, varscan2
- REV3L | c.139+10705G>C | Intron (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- RMDN2 | c.452+21925C>G | Intron (SNP) | VAF 26/213 reads (12%) | catalogued as COSV52227179; called by muse, mutect2, varscan2
- RNASEH2C | c.-15C>T | 5'UTR (SNP) | VAF 43/177 reads (24%) | catalogued as rs1397002568, COSV57730133; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2907G>T | RNA (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- SEPTIN7 | c.62-1264dup | Intron (INS) | VAF 12/62 reads (19%) | catalogued as rs1195487734; called by mutect2, varscan2
- SLC35A4 | c.*34G>A | 3'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- TMEM70 | c.*171A>T | 3'UTR (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- TUT1 | chr11:62591585 G>C | 5'Flank (SNP) | VAF 11/47 reads (23%) | catalogued as rs982207760; called by muse, mutect2
- TYROBP | c.229+24T>A | Intron (SNP) | VAF 28/128 reads (22%) | catalogued as rs781498043; called by muse, mutect2, varscan2
